Somatic mutation profile of tumor specimen TARGET-30-PARKNP-01A (aliquot TARGET-30-PARKNP-01A-01D) from TARGET case TARGET-30-PARKNP, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 8.8 years (3,214 days).
Specimen TARGET-30-PARKNP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ca41a1c-cb7c-4307-a4ba-30d02ec6de47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARKNP-10A (Blood Derived Normal), aliquot TARGET-30-PARKNP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/478ff5b4-ac4a-44fc-8ccf-bce424be754b

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 15, Silent 11, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3520T>C p.F1174L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs281864719, CM113795, COSV66556166, COSV66559314, COSV66568713; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AOX1 | c.1342T>A p.F448I | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65981536; called by muse, mutect2, varscan2
- CDCA7L | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62259127; called by muse, mutect2, varscan2
- HUNK | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.053); catalogued as COSV54228240; called by muse, mutect2, varscan2
- L3MBTL3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62386174; called by muse, mutect2, varscan2
- LILRA4 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs560878491, COSV52492220, COSV52496130; called by muse, mutect2, varscan2
- MEIOC | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs763940507, COSV63440095; called by muse, mutect2, varscan2
- NANOS2 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs151009341; called by muse, mutect2, varscan2
- NAP1L3 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100220263, COSV59075243; called by muse, mutect2, varscan2
- PSMD1 | c.304+2T>C p.X102_splice | Splice Site (SNP) | VAF 52/108 reads (48%) | catalogued as COSV58078711; called by muse, mutect2, varscan2
- SAMD9L | c.3857A>G p.E1286G | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59081457; called by muse, mutect2, varscan2
- SLC6A3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1172470054, COSV54364144; called by muse, mutect2, varscan2
- SREBF2 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV63331191; called by muse, mutect2, varscan2
- SREK1IP1 | c.423A>T p.E141D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as COSV72486231; called by muse, mutect2, varscan2
- SYNE2 | c.5758C>G p.Q1920E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV59940508, COSV59950723; called by muse, mutect2, varscan2
- ZFP64 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53799036; called by muse, mutect2, varscan2
- H2BC5 | c.191_194dup p.V67Lfs*78 (on ENST00000289316 / NM_138720.2; = p.V67Lfs*72 on NM_021063.4) | Frame Shift Ins (INS) | VAF 63/197 reads (32%) | called by mutect2, pindel, varscan2
- HERC1 | c.11980_11981del p.G3994Rfs*2 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- MSH2 | c.1530_1531del p.Q510Hfs*2 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- SLC39A2 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMRTC2 | c.834C>T p.C278= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1555837152, COSV54186661; called by muse, mutect2, varscan2
- EPC1 | c.2088C>T p.G696= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV53925738; called by muse, mutect2, varscan2
- FBN3 | c.4845C>A p.I1615= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV54460279; called by muse, mutect2, varscan2
- FBXL14 | c.726G>A p.S242= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV59336248; called by muse, mutect2, varscan2
- FGF7 | c.243A>G p.K81= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV51066080; called by muse, mutect2, varscan2
- GTSE1 | c.345C>T p.S115= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs546328576, COSV71889056; called by muse, mutect2, varscan2
- KLHL4 | c.1152T>C p.L384= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- LATS2 | c.2082C>T p.Y694= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs150375162; called by muse, mutect2, varscan2
- MCTP1 | c.969A>G p.P323= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2
- OR1S1 | c.711T>A p.A237= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV58707072; called by muse, mutect2, varscan2
- SLFN13 | c.828A>T p.A276= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as COSV53193479; called by muse, mutect2, varscan2
